Somatic mutation profile of tumor specimen MMRF_1073_1_BM_CD138pos (aliquot MMRF_1073_1_BM_CD138pos_T1_KHS5U_L08711) from MMRF case MMRF_1073, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,748 days).
Specimen MMRF_1073_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7e0ba6d-fa2a-4efd-bf46-6e693560489b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1073_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1073_2_PB_WBC_C1_KHS5U_L08710; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6c34321-5dc3-44de-b534-190b0d9e1331

The open-access MAF lists 125 somatic variants for this specimen: 47 protein-altering or splice-affecting, 20 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 36, Silent 20, Intron 12, 3'Flank 4, Frame Shift Del 3, 5'UTR 3, Nonsense Mutation 2, RNA 2, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 113/615 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs755058216, COSV68068956; called by muse, mutect2, varscan2
- CDH17 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV50327264; called by muse, mutect2, varscan2
- CEP120 | c.1747G>T p.V583F | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs770298645; called by muse, mutect2, varscan2
- CFAP65 | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370571954; called by muse, mutect2, varscan2
- CSF1R | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 94/140 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs576921324; called by muse, mutect2, varscan2
- DLEC1 | c.4386C>A p.Y1462* | Nonsense Mutation (SNP) | VAF 11/203 reads (5%) | catalogued as COSV57300488; called by muse, mutect2
- FAM91A1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769005370; called by muse, mutect2, varscan2
- GCN1 | c.4196A>G p.Y1399C | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748844667; called by muse, mutect2, varscan2
- HDC | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 227/769 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768687991, COSV51068285; called by muse, mutect2, varscan2
- IGKV1-5 | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs111612902; called by muse, mutect2, varscan2
- IGSF9B | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374101848; called by muse, mutect2
- ISLR | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1253096514; called by muse, mutect2
- KRT74 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs748212385, COSV59771429; called by muse, mutect2, varscan2
- LAS1L | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as rs759676837; called by muse, mutect2, varscan2
- PLXNB3 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs868950741; called by muse, varscan2
- QARS1 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 143/249 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs765660706; called by muse, mutect2, varscan2
- RAPGEF5 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as rs774754319; called by muse, mutect2, varscan2
- RBM10 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1556777479; called by muse, mutect2, varscan2
- SGSM1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs368742437; called by muse, mutect2, varscan2
- TTC28 | c.6553G>A p.G2185S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs553471572; called by muse, mutect2, varscan2
- WIPI1 | c.444_447del p.I150Tfs*13 | Frame Shift Del (DEL) | VAF 26/107 reads (24%) | catalogued as rs759604536; called by mutect2, pindel, varscan2
- ZNF541 | c.2057C>A p.T686N | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV54546755; called by muse, mutect2, varscan2
- AWAT2 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- C10orf120 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CDH1 | c.549C>A p.D183E | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CEP295 | c.2205G>T p.R735S | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- COPB2 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- DPYD | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSPP | c.168_172dup p.G58Efs*33 | Frame Shift Ins (INS) | VAF 66/150 reads (44%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ETV1 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- GPATCH8 | c.2711A>G p.H904R | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- H4C5 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- IQSEC1 | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2
- KIAA0825 | c.1864T>C p.F622L | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LAMA5 | c.1785del p.L595Ffs*108 | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | called by mutect2, pindel, varscan2
- MX2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MYO10 | c.2671C>T p.L891F | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- NUP155 | c.2335C>A p.Q779K (on ENST00000231498 / NM_153485.3; = p.Q720K on NM_004298.4) | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PSMB10 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASGRF1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TENT5C | c.286del p.H96Mfs*22 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | called by mutect2, pindel, varscan2
- TNS1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 64/125 reads (51%) | called by muse, mutect2, varscan2
- TOPBP1 | c.3819_3821del p.S1274del | In Frame Del (DEL) | VAF 12/60 reads (20%) | called by pindel, varscan2
- UNC79 | c.1088C>A p.P363Q (on ENST00000393151 / NM_001346218.2; = p.P186Q on NM_020818.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ZNF227 | c.1470A>C p.K490N | Missense Mutation (SNP) | VAF 121/199 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CCDC88C | c.1782C>A p.A594= | Silent (SNP) | VAF 45/243 reads (19%) | called by muse, mutect2, varscan2
- FBXO17 | c.228A>T p.A76= | Silent (SNP) | VAF 36/386 reads (9%) | called by muse, mutect2
- FOXL3 | c.102G>A p.A34= | Silent (SNP) | VAF 46/194 reads (24%) | catalogued as COSV101546378; called by muse, mutect2, varscan2
- GAB1 | c.921T>C p.Y307= | Silent (SNP) | VAF 145/259 reads (56%) | catalogued as rs1183831518; called by muse, mutect2, varscan2
- HAUS7 | c.142C>T p.L48= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- HERC1 | c.2391A>C p.L797= | Silent (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- HERC6 | c.3069A>G p.*1023= | Silent (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- IGLL5 | c.177C>T p.S59= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs569308745, COSV104440313, COSV73250973; called by muse, mutect2, varscan2
- KLC1 | c.1098C>T p.L366= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- MED23 | c.972G>A p.G324= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as COSV100645450; called by muse, mutect2, varscan2
- NALCN | c.75G>A p.S25= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs374635988, COSV51922893; called by muse, mutect2
- NPFFR1 | c.378T>G p.S126= | Silent (SNP) | VAF 82/253 reads (32%) | called by muse, mutect2, varscan2
- PNMA2 | c.6G>A p.A2= | Silent (SNP) | VAF 8/207 reads (4%) | catalogued as rs924910659, COSV72908551; called by muse, mutect2
- POM121L2 | c.1206T>C p.N402= | Silent (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- PTGS2 | c.511A>C p.R171= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV66568283; called by muse, mutect2, varscan2
- RAB3GAP1 | c.489G>C p.V163= | Silent (SNP) | VAF 68/193 reads (35%) | called by muse, mutect2, varscan2
- RBMX | c.954C>T p.D318= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs763312129, COSV57811187; called by muse, mutect2, varscan2
- SHANK2 | c.3255C>T p.A1085= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs1555154088; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.93G>A p.V31= | Silent (SNP) | VAF 42/282 reads (15%) | called by muse, mutect2, varscan2
- VNN1 | c.435C>T p.C145= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as rs376241655, COSV63390080; called by muse, mutect2, varscan2
- ADAMTS3 | c.*2005G>A | 3'UTR (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- AQP1 | c.*4G>T | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- BICC1 | c.2533+292C>G | Intron (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- C10orf90 | c.1720-28A>C | Intron (SNP) | VAF 65/125 reads (52%) | called by muse, mutect2, varscan2
- C9orf163 | n.87C>T | RNA (SNP) | VAF 48/281 reads (17%) | called by muse, mutect2, varscan2
- CAPN3 | c.1783-116C>T | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CSNK1G3 | chr5:123616324 A>T | 3'Flank (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- CTDSP1 | c.657+154C>T | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- DCAF17 | c.*1843_*1854del | 3'UTR (DEL) | VAF 11/84 reads (13%) | called by mutect2, pindel
- DEDD | c.*572C>G | 3'UTR (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- DGKH | c.*510C>G | 3'UTR (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- DIO2 | c.*4722T>A | 3'UTR (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- DIP2C | c.157+1645G>A | Intron (SNP) | VAF 37/86 reads (43%) | catalogued as rs550686571; called by muse, mutect2, varscan2
- DISC1 | c.*4105C>T | 3'UTR (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- DIXDC1 | c.656+596A>C | Intron (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- DOCK11 | c.3292+499T>G | Intron (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99354758; called by muse, mutect2, varscan2
- ELP4 | chr11:31786693 G>T | 3'Flank (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- FGFR2 | c.*661del | 3'UTR (DEL) | VAF 18/44 reads (41%) | catalogued as rs533680275; called by mutect2, varscan2
- GLB1L3 | chr11:134276288 G>A | 5'Flank (SNP) | VAF 83/460 reads (18%) | called by muse, mutect2, varscan2
- H4C9 | c.*56C>G | 3'UTR (SNP) | VAF 40/89 reads (45%) | catalogued as rs188731680, COSV62889813; called by muse, mutect2, varscan2
- HEPACAM | c.*1557G>A | 3'UTR (SNP) | VAF 10/84 reads (12%) | catalogued as rs1004636554; called by muse, mutect2
- HSD11B1 | c.*205A>G | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- IDS | c.1007-91T>G | Intron (SNP) | VAF 90/220 reads (41%) | called by muse, mutect2, varscan2
- ING5 | c.*694G>A | 3'UTR (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- KRTAP10-5 | c.-9C>A | 5'UTR (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- LAMA4 | c.*456T>G | 3'UTR (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- LGR5 | c.*513C>T | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- LIFR | c.*5381T>G | 3'UTR (SNP) | VAF 109/172 reads (63%) | called by muse, mutect2, varscan2
- LRRC20 | c.*665G>A | 3'UTR (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- LRRC73 | c.-871del | 5'UTR (DEL) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- LSS | c.1989-615T>C | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs111494706; called by muse, mutect2, varscan2
- MAP3K2 | c.*6619A>C | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- MIPOL1 | c.*1799G>A | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- MMP15 | c.*490G>A | 3'UTR (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- MMP15 | c.*733C>T | 3'UTR (SNP) | VAF 90/143 reads (63%) | called by muse, varscan2
- MPLKIP | c.*169T>C | 3'UTR (SNP) | VAF 31/124 reads (25%) | called by muse, mutect2, varscan2
- NFKB2 | c.145-26A>G | Intron (SNP) | VAF 76/172 reads (44%) | called by muse, mutect2, varscan2
- NOTUM | c.*5A>G | 3'UTR (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- ODF3B | c.*40G>A | 3'UTR (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*1364G>T | 3'UTR (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- PFDN6 | c.*57T>C | 3'UTR (SNP) | VAF 28/75 reads (37%) | catalogued as rs1262883933; called by muse, mutect2, varscan2
- PIGP | c.*2210G>A | 3'UTR (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- PIM2 | c.-95C>T | 5'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- PRELID3B | c.*1671A>G | 3'UTR (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.295+424T>C | Intron (SNP) | VAF 66/126 reads (52%) | catalogued as rs1331228942; called by muse, mutect2, varscan2
- SH2B3 | c.*3197A>C | 3'UTR (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143625471 A>C | 3'Flank (SNP) | VAF 49/123 reads (40%) | called by muse, mutect2, varscan2
- SLN | c.*179A>G | 3'UTR (SNP) | VAF 8/108 reads (7%) | catalogued as rs1002885517; called by muse, mutect2
- SNTB2 | c.*1155G>A | 3'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- SPAG9 | c.*2803A>G | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- STIMATE | c.*2488_*2507del | 3'UTR (DEL) | VAF 9/124 reads (7%) | catalogued as COSV104422124; called by mutect2, varscan2
- STXBP5 | c.917+1118A>G | Intron (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*3660G>T | 3'UTR (SNP) | VAF 8/147 reads (5%) | catalogued as COSV101467769; called by muse, mutect2
- TLR4 | c.*1835A>T | 3'UTR (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- TPD52L3 | chr9:6330893 ins C | 3'Flank (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- TSBP1-AS1 | n.4G>T | RNA (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.*849A>C | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ZADH2 | c.*5448C>T | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
